CPTAC case C3L-02665 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c97152dc-91b5-4250-a35f-e98a9c4df909

Demographics
Sex at birth: male; Race: white; Year of birth: 1966; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Middle lobe, lung; Age at diagnosis: 51.1 years (18,659 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T3; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 3 days; Days to last follow up: 3 days; Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 6 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Margin status: Indeterminate.

Follow-up (1 entry)
- Days to follow up: 3 days; Disease response: Tumor Free.

Other clinical attributes
- Weight: 80 kg; Height: 178 cm; BMI: 25.25; FEV1/FVC before bronchodilator (%): 72.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 29; Cigarettes per day: 20; Tobacco smoking onset year: 1988; Exposure duration years: 34.

Biospecimens (9 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02665-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 49 mg; Time between clamping and freezing: 16 minutes; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02665-21: Section location: Right Middle Lobe; Percent tumor nuclei: 85; Percent necrosis: 3.
- Sample C3L-02665-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 60 mg; Time between clamping and freezing: 18 minutes; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02665-22: Section location: Right Middle Lobe; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3L-02665-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 30 mg; Time between clamping and freezing: 19 minutes; Time between excision and freezing: 13 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02665-23: Section location: Right Middle Lobe; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3L-02665-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 27 mg; Time between clamping and freezing: 21 minutes; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02665-24: Section location: Right Middle Lobe; Percent tumor nuclei: 80; Percent necrosis: 3.
- Sample C3L-02665-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 50 mg; Time between clamping and freezing: 22 minutes; Time between excision and freezing: 16 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02665-25: Section location: Right Middle Lobe; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-02665-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 62 mg; Time between clamping and freezing: 25 minutes; Time between excision and freezing: 19 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02665-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 66 mg; Time between clamping and freezing: 26 minutes; Time between excision and freezing: 20 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02665-08: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 76 mg; Time between clamping and freezing: 28 minutes; Time between excision and freezing: 22 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02665-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
